Somatic mutation profile of tumor specimen ALCH-B1NF-TTP1-A (aliquot ALCH-B1NF-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1NF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.9 years (27,731 days).
Specimen ALCH-B1NF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57ed1d89-756d-4f38-88e2-b5d5ace5ebbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1NF-NB1-A (Blood Derived Normal), aliquot ALCH-B1NF-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70b749f6-ec3c-4d5f-a465-5967ac73c3b0

The open-access MAF lists 231 somatic variants for this specimen: 162 protein-altering or splice-affecting, 50 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 50, Intron 9, Splice Site 7, Nonsense Mutation 6, 3'UTR 4, RNA 4, Frame Shift Del 3, Splice Region 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HCN1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs587777495, CM145438, COSV57542899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.1197G>A p.P399= | Splice Region (SNP) | VAF 38/634 reads (6%) | catalogued as rs768701595, CS097758; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ABTB1 | c.581A>G p.Q194R (on ENST00000232744 / NM_172027.3; = p.Q52R on NM_032548.3) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as rs1376902949; called by muse, mutect2
- ADAMTS12 | c.3113C>A p.P1038H | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV61273049; called by muse, mutect2, varscan2
- ADAMTS3 | c.2848T>C p.C950R | Missense Mutation (SNP) | VAF 70/1060 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54390278; called by muse, mutect2
- ANKRD36B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51536395; called by muse, mutect2, varscan2
- C10orf120 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100271722, COSV61491617; called by muse, mutect2, varscan2
- CACNA1F | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.333); catalogued as rs782649560, COSV100544553; called by muse, mutect2, varscan2
- CAPN6 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759834539, COSV60695723; called by muse, mutect2, varscan2
- CD36 | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs367954954; called by muse, mutect2, varscan2
- CLEC4C | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63582218, COSV63582649; called by muse, mutect2, varscan2
- CNTN1 | c.2725C>G p.P909A | Missense Mutation (SNP) | VAF 28/859 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100751668; called by muse, mutect2
- CSMD3 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52221127; called by muse, mutect2, varscan2
- DBH | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748341921, COSV99708156; called by muse, mutect2, varscan2
- DCC | c.3764C>T p.T1255M | Missense Mutation (SNP) | VAF 71/524 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs775848107, COSV101473552, COSV71434183; called by muse, mutect2, varscan2
- DUOX2 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 80/532 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758697659, COSV101199706; called by muse, mutect2, varscan2
- DYTN | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 37/438 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs1237451427, COSV101123950; called by muse, mutect2
- EGFLAM | c.2644G>A p.D882N (on ENST00000354891 / NM_001205301.2; = p.D874N on NM_152403.4) | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV100380907; called by muse, mutect2, varscan2
- ELAVL4 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV100836575; called by muse, mutect2, varscan2
- EP400 | c.7560G>C p.Q2520H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.66); catalogued as rs1171700482; called by muse, mutect2, varscan2
- ESR1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 58/598 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52783819; called by muse, mutect2
- FAM47A | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as COSV60494930, COSV60497206; called by muse, mutect2, varscan2
- FCRL2 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs769609452, COSV100829963, COSV100830003; called by muse, mutect2, varscan2
- FLNB | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914423; called by muse, mutect2, varscan2
- GLRA2 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV54346748; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated, low confidence (0.32); catalogued as rs1403732792; called by muse, mutect2
- H4-16 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63761996; called by muse, mutect2, varscan2
- KCNA4 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100069304; called by muse, mutect2, varscan2
- KCNQ5 | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs1382548306; called by muse, mutect2
- KRT14 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 109/543 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV51421665; called by muse, mutect2, varscan2
- MAP3K19 | c.3381G>T p.L1127F | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376709407; called by muse, mutect2, varscan2
- MYO10 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs776689049; called by muse, mutect2, varscan2
- MYO7B | c.6226C>G p.R2076G | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100264687; called by muse, mutect2, varscan2
- NES | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100957742; called by muse, mutect2, varscan2
- NOP2 | c.1789+1G>T p.X597_splice (on ENST00000322166 / NM_001258308.2; = p.X593_splice on NM_006170.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/141 reads (11%) | catalogued as COSV59109453; called by muse, mutect2, varscan2
- ONECUT2 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs1423198413; called by muse, mutect2
- OR10J1 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 87/586 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV71129689; called by muse, mutect2, varscan2
- OR4Q3 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 58/674 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59180664; called by muse, mutect2
- OR6K3 | c.458C>T p.T153I (on ENST00000368146; = p.T137I on NM_001005327.2) | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV100933917; called by muse, mutect2, varscan2
- PCDHB2 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 97/625 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50564098; called by muse, mutect2, varscan2
- PDE10A | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 31/215 reads (14%) | catalogued as COSV63100829; called by muse, mutect2, varscan2
- PEX19 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs766423323; called by muse, mutect2, varscan2
- PLK2 | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 53/782 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.119); catalogued as rs1240702031; called by muse, mutect2
- PPP1R3A | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 62/440 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as COSV52881943; called by muse, mutect2
- PRRC2B | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 21/140 reads (15%) | catalogued as rs1459959381; called by muse, mutect2, varscan2
- PTPRT | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 126/476 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61991789; called by muse, mutect2, varscan2
- RAB11A | c.35T>G p.F12C | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV56042659; called by muse, mutect2
- RAB3GAP2 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 80/745 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs765340567; called by muse, mutect2, varscan2
- SERAC1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 49/482 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs148861818; called by muse, mutect2, varscan2
- SLC15A4 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57161070; called by muse, mutect2, varscan2
- SLC2A9 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1360570041; called by muse, mutect2
- SLC44A5 | c.974G>T p.W325L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100901537; called by muse, mutect2
- ST18 | c.2012A>C p.N671T | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766171208; called by muse, mutect2, varscan2
- ST6GAL2 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 22/156 reads (14%) | PolyPhen benign (0.003); catalogued as rs920131957, COSV100868308; called by muse, mutect2, varscan2
- TAAR2 | c.639G>T p.L213F (on ENST00000367931 / NM_001033080.1; = p.L168F on NM_014626.3) | Missense Mutation (SNP) | VAF 59/586 reads (10%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.941); catalogued as rs775441477; called by muse, mutect2
- TIMMDC1 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 73/417 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as rs940988515; called by muse, mutect2, varscan2
- TMEM132D | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67159575; called by muse, mutect2, varscan2
- TRIM51GP | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs778251232; called by muse, mutect2, varscan2
- TRPC7 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV61456284; called by muse, mutect2, varscan2
- TSC1 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 72/418 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs118203381, CM095661; ClinVar: not provided; called by muse, mutect2, varscan2
- USH2A | c.9613C>A p.R3205S | Missense Mutation (SNP) | VAF 93/710 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100231489, COSV56337880; called by muse, mutect2, varscan2
- ZNF283 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1568426818; called by muse, mutect2
- ZNF99 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as COSV68055536; called by muse, mutect2, varscan2
- ZNRF4 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs753008591, COSV99706653; called by muse, mutect2, varscan2
- ZRANB2 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs137863951; called by muse, mutect2
- ACAN | c.4912C>G p.L1638V | Missense Mutation (SNP) | VAF 100/605 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ACTBL2 | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ADGRB1 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- ANKRD26 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 69/587 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARAP3 | c.2965G>C p.D989H | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP13A5 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C7 | c.2461G>T p.G821C | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C9orf116 | c.80A>C p.Y27S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CAPN10 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH12 | c.2158A>T p.R720W | Missense Mutation (SNP) | VAF 54/761 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- CDH19 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 60/583 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CEMIP | c.1411+2_1411+5del p.X471_splice | Splice Site (DEL) | VAF 44/454 reads (10%) | called by mutect2, pindel
- CLSTN2 | c.2683G>T p.G895W | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.624); called by muse, varscan2
- CLSTN2 | c.2684G>T p.G895V | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.054); called by muse, varscan2
- COBLL1 | c.3199G>T p.A1067S (on ENST00000392717; = p.A1029S on NM_014900.5) | Missense Mutation (SNP) | VAF 74/690 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKI | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EFHC2 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EMC7 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FANCM | c.3103A>T p.T1035S | Missense Mutation (SNP) | VAF 91/820 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FLT3 | c.1837G>T p.G613W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR52 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- GRIA2 | c.385A>T p.R129* | Nonsense Mutation (SNP) | VAF 64/878 reads (7%) | called by muse, mutect2
- GUCY1A1 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HDAC9 | c.3181del p.E1061Sfs*49 (on ENST00000441542 / NM_178425.3; = p.E1058Sfs*49 on NM_178423.3) | Frame Shift Del (DEL) | VAF 41/318 reads (13%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.4616A>G p.K1539R | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HTATIP2 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICAM1 | c.926-1G>T p.X309_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- IGF2R | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- IGHV3-74 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- IL27RA | c.1149C>A p.F383L | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INTS3 | c.269G>T p.C90F | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IRAK4 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPRID2 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 50/578 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.242); called by muse, mutect2
- KDR | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 192/490 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KPRP | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LAMA1 | c.5465C>G p.A1822G | Missense Mutation (SNP) | VAF 98/581 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MAP2K2 | c.319_324del p.I107_K108del | In Frame Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel
- MAP4K3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MARCKS | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MARK4 | c.905A>T p.E302V | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- MEGF8 | c.352-1G>A p.X118_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- MFAP5 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MRC2 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.41738T>G p.V13913G | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MYH13 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYO10 | c.1390A>C p.K464Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2
- NBPF26 | c.2356G>A p.V786I (on ENST00000620612; = p.V524I on NM_001351372.1) | Missense Mutation (SNP) | VAF 58/575 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- NES | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.4463A>G p.K1488R | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- NOTCH1 | c.93C>G p.C31W | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR14K1 | c.149A>T p.D50V | Missense Mutation (SNP) | VAF 54/423 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR2L5 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 71/472 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR2M5 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 65/537 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- OR3A3 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OTOG | c.2775_2776insA p.G926Rfs*73 | Frame Shift Ins (INS) | VAF 39/128 reads (30%) | called by mutect2, pindel*, varscan2
- P2RY12 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PACC1 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- PACSIN1 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 26/311 reads (8%) | called by muse, mutect2
- PCDHB3 | c.1910A>T p.K637M | Missense Mutation (SNP) | VAF 94/648 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PIM3 | c.195+1G>T p.X65_splice | Splice Site (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- PLA2G15 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCB4 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 94/406 reads (23%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- POLQ | c.5536T>C p.C1846R | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PPP1R3A | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 64/446 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- PRDM9 | c.1216C>A p.H406N | Missense Mutation (SNP) | VAF 95/750 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRIMPOL | c.747A>C p.K249N | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PTPRD | c.3796G>T p.G1266C | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- REC8 | c.126-2A>G p.X42_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- RELCH | c.705A>T p.L235F | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- REV3L | c.8101A>T p.K2701* | Nonsense Mutation (SNP) | VAF 36/518 reads (7%) | called by muse, mutect2
- RPS2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- RPUSD3 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SASH1 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SBSN | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 82/545 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SCN7A | c.3755del p.A1252Vfs*15 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel
- SEL1L2 | c.926T>A p.I309N | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEMA3E | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 64/457 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SIN3B | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SIPA1L2 | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.044); called by muse, mutect2
- SLC22A4 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SLC25A31 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- SLC66A1 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TDRD5 | c.1555T>A p.Y519N | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132D | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2
- TP53 | c.504_505del p.M169Dfs*11 | Frame Shift Del (DEL) | VAF 24/200 reads (12%) | called by pindel, varscan2
- TRIP13 | c.1206C>T p.A402= | Splice Region (SNP) | VAF 67/257 reads (26%) | called by muse, mutect2, varscan2
- TRPC7 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTC39A | c.697-2A>C p.X233_splice (on ENST00000447632 / NM_001297665.1; = p.X198_splice on NM_001080494.3) | Splice Site (SNP) | VAF 51/278 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.8017A>T p.K2673* (on ENST00000591111; = p.K2627* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 106/808 reads (13%) | called by muse, mutect2, varscan2
- UNC5A | c.2276T>A p.I759N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USH2A | c.14471C>A p.T4824N | Missense Mutation (SNP) | VAF 64/551 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VPS4B | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- XIRP2 | c.1330T>C p.W444R (on ENST00000628543; = p.W619R on NM_152381.6) | Missense Mutation (SNP) | VAF 60/562 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ZBED9 | c.3874A>G p.R1292G | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZEB1 | c.1038T>G p.I346M | Missense Mutation (SNP) | VAF 94/543 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZFHX4 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZNF257 | c.524G>T p.C175F | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ACD | c.609T>C p.Y203= (on ENST00000620338; = p.Y114= on NM_022914.3) | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, varscan2
- ADCY1 | c.198C>G p.A66= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as rs968647729; called by muse, mutect2, varscan2
- APBA3 | c.1635G>A p.L545= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2664C>G p.G888= (on ENST00000545399 / NM_001256214.2; = p.G875= on NM_152296.5) | Silent (SNP) | VAF 70/386 reads (18%) | called by muse, mutect2, varscan2
- BBS7 | c.984A>T p.P328= | Silent (SNP) | VAF 51/386 reads (13%) | called by muse, mutect2, varscan2
- CACNA1E | c.6189C>T p.H2063= (on ENST00000367573 / NM_001205293.3; = p.H2020= on NM_000721.4) | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as rs755046974; called by muse, mutect2, varscan2
- CADPS | c.1887T>G p.P629= | Silent (SNP) | VAF 50/342 reads (15%) | called by muse, mutect2, varscan2
- CEBPD | c.213G>A p.V71= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- COL4A1 | c.4008C>A p.V1336= | Silent (SNP) | VAF 74/581 reads (13%) | called by muse, mutect2, varscan2
- COL4A2 | c.1962G>T p.G654= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100847099; called by muse, mutect2, varscan2
- CPS1 | c.4284A>G p.R1428= | Silent (SNP) | VAF 36/372 reads (10%) | called by muse, mutect2
- CSAG2 | c.231A>G p.P77= | Silent (SNP) | VAF 56/190 reads (29%) | called by mutect2, varscan2
- ENPEP | c.1173T>C p.V391= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, mutect2, varscan2
- ERBB2 | c.1554G>T p.G518= | Silent (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- FAP | c.48G>T p.V16= | Silent (SNP) | VAF 22/568 reads (4%) | called by muse, mutect2
- FHL5 | c.300C>A p.S100= | Silent (SNP) | VAF 9/175 reads (5%) | catalogued as COSV58734999, COSV58735731; called by muse, mutect2
- GLRB | c.1170G>A p.G390= | Silent (SNP) | VAF 66/433 reads (15%) | catalogued as COSV52416062; called by muse, mutect2, varscan2
- H1-5 | c.129C>T p.V43= | Silent (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- HTRA3 | c.357C>T p.R119= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.102G>T p.G34= | Silent (SNP) | VAF 53/308 reads (17%) | catalogued as rs782528998; called by muse, mutect2, varscan2
- IGLON5 | c.249G>A p.P83= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs761843019; called by muse, mutect2, varscan2
- ITPR1 | c.5124G>A p.P1708= (on ENST00000354582; = p.P1702= on NM_001168272.2) | Silent (SNP) | VAF 19/321 reads (6%) | catalogued as rs759857013, COSV56967141; called by muse, mutect2
- ITPR3 | c.78C>A p.I26= | Silent (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- KBTBD3 | c.1161A>T p.S387= | Silent (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- KIF2B | c.312G>A p.S104= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs543663752, COSV52129067, COSV52133640; called by muse, mutect2
- KYNU | c.87G>T p.V29= | Silent (SNP) | VAF 71/449 reads (16%) | called by muse, mutect2, varscan2
- LDLRAD3 | c.231C>T p.P77= | Silent (SNP) | VAF 71/476 reads (15%) | called by muse, mutect2, varscan2
- LRP1B | c.11088G>A p.E3696= | Silent (SNP) | VAF 54/461 reads (12%) | catalogued as rs1296361888; called by muse, mutect2, varscan2
- LRRC31 | c.192A>G p.S64= | Silent (SNP) | VAF 23/217 reads (11%) | called by muse, mutect2, varscan2
- MBTD1 | c.549A>T p.T183= | Silent (SNP) | VAF 81/430 reads (19%) | called by muse, mutect2, varscan2
- MICAL1 | c.15C>T p.T5= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs754447947; called by muse, mutect2, varscan2
- MOGS | c.51G>T p.R17= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- MSRA | c.423C>T p.H141= | Silent (SNP) | VAF 45/246 reads (18%) | catalogued as rs367978405; called by muse, mutect2, varscan2
- MYO1A | c.879C>T p.I293= | Silent (SNP) | VAF 39/311 reads (13%) | called by muse, mutect2, varscan2
- NLRC4 | c.1749C>T p.S583= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1387C>T p.L463= | Silent (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- PLCH1 | c.534G>A p.L178= (on ENST00000340059 / NM_001130960.2; = p.L190= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/338 reads (12%) | called by muse, mutect2, varscan2
- PPARGC1A | c.1681A>C p.R561= | Silent (SNP) | VAF 25/440 reads (6%) | called by muse, mutect2
- SLC8A1 | c.2829C>A p.A943= | Silent (SNP) | VAF 67/542 reads (12%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1413C>T p.P471= | Silent (SNP) | VAF 119/786 reads (15%) | called by muse, mutect2, varscan2
- SPTA1 | c.2955A>G p.L985= | Silent (SNP) | VAF 76/532 reads (14%) | catalogued as rs1418513637; called by muse, mutect2, varscan2
- TEX15 | c.1614A>G p.K538= (on ENST00000256246; = p.K921= on NM_001350162.2) | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- TSPAN33 | c.222C>T p.L74= | Silent (SNP) | VAF 43/287 reads (15%) | catalogued as rs746924179, COSV56828096; called by muse, mutect2, varscan2
- UNKL | c.1008C>T p.S336= | Silent (SNP) | VAF 46/249 reads (18%) | catalogued as rs748099475; called by muse, mutect2, varscan2
- UROC1 | c.1851G>A p.G617= | Silent (SNP) | VAF 23/372 reads (6%) | called by muse, mutect2
- USH2A | c.14472C>A p.T4824= | Silent (SNP) | VAF 63/549 reads (11%) | catalogued as COSV56367374; called by muse, mutect2, varscan2
- USP42 | c.3276G>A p.P1092= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs1481056650, COSV60357410; called by muse, mutect2, varscan2
- ZFHX4 | c.5001C>G p.A1667= | Silent (SNP) | VAF 31/235 reads (13%) | called by muse, mutect2, varscan2
- ZNF676 | c.1188C>T p.P396= (on ENST00000650058; = p.P364= on NM_001001411.3) | Silent (SNP) | VAF 82/525 reads (16%) | catalogued as COSV68092734; called by muse, varscan2
- ZSCAN18 | c.729G>T p.R243= | Silent (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- ACAD9 | c.150+40C>T | Intron (SNP) | VAF 68/569 reads (12%) | called by muse, mutect2, varscan2
- AGXT | c.847-174C>T | Intron (SNP) | VAF 10/71 reads (14%) | catalogued as rs1191373107; called by muse, mutect2, varscan2
- ANK1 | c.5619+338C>T | Intron (SNP) | VAF 51/309 reads (17%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*63G>T | 3'UTR (SNP) | VAF 56/297 reads (19%) | catalogued as COSV100659593; called by muse, mutect2, varscan2
- CYGB | c.*883G>T | 3'UTR (SNP) | VAF 29/423 reads (7%) | called by muse, mutect2
- FAM172BP | n.517C>A | RNA (SNP) | VAF 28/215 reads (13%) | called by muse, mutect2, varscan2
- GPN1 | c.111+236C>T | Intron (SNP) | VAF 41/388 reads (11%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1556G>C | RNA (SNP) | VAF 43/739 reads (6%) | catalogued as rs774836694; called by muse, mutect2
- IGKV2OR22-4 | n.119C>A | RNA (SNP) | VAF 30/1136 reads (3%) | called by muse, mutect2
- INTS4 | c.246+3478C>T | Intron (SNP) | VAF 47/261 reads (18%) | called by muse, mutect2, varscan2
- LVRN | c.-66G>T | 5'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- MCFD2 | c.150-41A>T | Intron (SNP) | VAF 118/486 reads (24%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+3537A>G | Intron (SNP) | VAF 73/402 reads (18%) | catalogued as rs757569160; called by muse, mutect2, varscan2
- PRCD | chr17:76544654 G>C | 3'Flank (SNP) | VAF 142/547 reads (26%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.*238C>T | 3'UTR (SNP) | VAF 83/289 reads (29%) | called by muse, mutect2, varscan2
- SAC3D1 | c.-8+34G>T | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2897C>T | RNA (SNP) | VAF 59/466 reads (13%) | catalogued as rs773254318; called by muse, mutect2, varscan2
- TAP1 | c.*24C>G | 3'UTR (SNP) | VAF 72/400 reads (18%) | called by muse, mutect2, varscan2
- ZNF638 | c.2378-2566C>G | Intron (SNP) | VAF 113/463 reads (24%) | called by muse, mutect2, varscan2
